Somatic mutation profile of tumor specimen TCGA-SU-A7E7-01A (aliquot TCGA-SU-A7E7-01A-22D-A33T-08) from TCGA case TCGA-SU-A7E7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.7 years (22,185 days).
Specimen TCGA-SU-A7E7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91180081-3e49-4d97-8859-c31d8cc90b56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SU-A7E7-10A (Blood Derived Normal), aliquot TCGA-SU-A7E7-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51963a52-1b83-4662-946d-c21beb6b5562

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA8 | c.625+2T>G p.X209_splice | Splice Site (SNP) | VAF 14/130 reads (11%) | catalogued as COSV100526742; called by muse, mutect2
- CCNK | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV101110335; called by muse, mutect2, varscan2
- CTCF | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1259610303, COSV50506072; called by muse, mutect2
- DISP1 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99450316; called by muse, mutect2, varscan2
- DMRTC2 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV99523332, COSV99523397; called by muse, mutect2
- EPN2 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100127444; called by muse, mutect2
- F11 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99251331; called by muse, mutect2, varscan2
- FAM47B | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); catalogued as COSV61452383; called by muse, mutect2
- MAGEC1 | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV53577064, COSV99595142; called by muse, mutect2, varscan2
- OR2AT4 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532291; called by muse, mutect2, varscan2
- SPATA6L | c.1128A>C p.R376S (on ENST00000461761 / NM_001353484.2; = p.R318S on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101121912; called by muse, mutect2
- STK10 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as COSV99451102; called by muse, mutect2
- TRPM5 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs781100696, COSV99329766; called by mutect2, varscan2
- TTN | c.43469C>A p.A14490D (on ENST00000591111; = p.A7066D on NM_003319.4) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV100600216; called by muse, mutect2, varscan2
- ZNF608 | c.1093T>A p.C365S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100101248; called by muse, mutect2
- ZNF823 | c.1772C>A p.A591E | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100362443; called by muse, mutect2
- RRP12 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- C5orf22 | c.138A>T p.V46= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as COSV100323413; called by muse, mutect2, varscan2
- SPECC1 | c.1818A>G p.L606= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs766473140, COSV99821445; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.324G>A p.P108= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs749880748, COSV50074081; called by muse, mutect2
- OBSCN | c.11660-2696C>G | Intron (SNP) | VAF 8/95 reads (8%) | catalogued as COSV99474876; called by muse, mutect2
